Somatic mutation profile of tumor specimen C3L-00401-01 (aliquot CPT0019300010_1) from CPTAC case C3L-00401, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.9 years (22,991 days).
Specimen C3L-00401-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8066f2f2-d888-4659-be6a-a4ffa85d6626.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00401-31 (Blood Derived Normal), aliquot CPT0019380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e802162b-c571-4206-a7dc-fdb58b17c7c5

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/888 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 48/1068 reads (4%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- CPAMD8 | c.2591G>A p.R864H (on ENST00000651564; = p.R817H on NM_015692.5) | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754265681; called by muse, mutect2
- FRY | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 38/800 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV66565996, COSV66574191; called by muse, mutect2
- HSPB2 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 50/866 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781794984, COSV57053047; called by muse, mutect2
- PGA5 | c.657C>T p.A219= | Splice Region (SNP) | VAF 97/2156 reads (4%) | catalogued as rs770670264; called by muse, mutect2
- SLC35A2 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs1023107993, COSV99504257; called by muse, mutect2
- BZW1 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 14/396 reads (4%) | called by muse, mutect2
- OR7D2 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- PHKA2 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 56/908 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC39A12 | c.920A>G p.D307G | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2
- TAZ | c.110-5G>A | Splice Region (SNP) | VAF 49/958 reads (5%) | called by muse, mutect2
- TNFRSF10D | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 28/642 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- ACP7 | c.198G>A p.P66= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as rs914671097; called by muse, mutect2
- ETNK2 | c.960C>T p.A320= | Silent (SNP) | VAF 25/682 reads (4%) | catalogued as rs959224768, COSV65819526; called by muse, mutect2
- PPP1R2C | c.126G>A p.K42= | Silent (SNP) | VAF 56/962 reads (6%) | called by muse, mutect2
- QRICH2 | c.3603C>T p.T1201= | Silent (SNP) | VAF 29/643 reads (5%) | catalogued as rs1242836840, COSV53155659; called by muse, mutect2
